Somatic mutation profile of tumor specimen C3L-06395-05 (aliquot CPT0363100009) from CPTAC case C3L-06395, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 62.7 years (22,896 days).
Specimen C3L-06395-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bc4d787-025e-4163-a8c4-59ec3e102bec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06395-31 (Blood Derived Normal), aliquot CPT0363160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55c6ac30-72d5-4632-a3c2-6ff0e87e4131

The open-access MAF lists 105 somatic variants for this specimen: 72 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 30, Intron 2, Frame Shift Del 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/344 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAM19 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 189/374 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57430088; called by muse, mutect2, varscan2
- ADAMTSL1 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 83/370 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771200194, COSV52821802; called by muse, mutect2, varscan2
- ARID3C | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 111/423 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52409278; called by muse, mutect2, varscan2
- C4orf51 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 137/383 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs772069422; called by muse, mutect2, varscan2
- CHD8 | c.6506A>G p.Q2169R (on ENST00000646647 / NM_001170629.2; = p.Q1890R on NM_020920.4) | Missense Mutation (SNP) | VAF 110/321 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1236235573; called by muse, mutect2, varscan2
- CNTN3 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 134/392 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV55166251, COSV55180654; called by muse, mutect2, varscan2
- CSNK1A1L | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 127/420 reads (30%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.06); catalogued as rs1475929700; called by muse, mutect2, varscan2
- EBF2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV68779997; called by muse, mutect2, varscan2
- EPHA6 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 195/369 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV101060623, COSV67562008; called by muse, mutect2, varscan2
- GABRA1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 141/537 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.88); catalogued as rs146134200; called by muse, mutect2, varscan2
- IL31RA | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1229853997; called by muse, mutect2, varscan2
- IMPG1 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV64061595; called by muse, mutect2, varscan2
- KANK2 | c.2505T>A p.F835L (on ENST00000586659 / NM_001379562.1; = p.F843L on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 170/468 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs377116202; called by muse, mutect2
- KNDC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 73/373 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs773651867; called by muse, mutect2, varscan2
- KRT6B | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 98/406 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs1472131132, COSV99360836; called by muse, mutect2, varscan2
- LMLN2 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 123/373 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1220613426; called by muse, mutect2, varscan2
- MAPKAP1 | c.1409C>G p.S470W (on ENST00000265960 / NM_001006617.3; = p.S434W on NM_024117.3) | Missense Mutation (SNP) | VAF 137/430 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56366320; called by muse, mutect2, varscan2
- MARCHF10 | c.1318T>C p.W440R | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV60885230; called by muse, mutect2, varscan2
- MGAM | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 102/422 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs782524066, COSV104438347; called by muse, mutect2, varscan2
- MMP26 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 89/459 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs773751132, COSV56172679; called by muse, mutect2, varscan2
- NACA2 | c.363A>G p.I121M | Missense Mutation (SNP) | VAF 161/495 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV71713196; called by muse, mutect2, varscan2
- OPRK1 | c.1097A>G p.D366G | Missense Mutation (SNP) | VAF 99/267 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as rs749254952; called by muse, mutect2, varscan2
- P2RX4 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 161/272 reads (59%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as rs766262361; called by muse, mutect2, varscan2
- PBX1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 178/587 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61533126; called by muse, mutect2, varscan2
- PCDH15 | c.3421C>G p.P1141A | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as rs764487129; called by muse, mutect2, varscan2
- PDE4DIP | c.3016A>G p.M1006V | Missense Mutation (SNP) | VAF 131/386 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs782380402; called by muse, mutect2, varscan2
- PTPRN | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1180844491, COSV55349208; called by muse, mutect2, varscan2
- PTPRT | c.4294G>A p.E1432K | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs568484928, COSV61963207, COSV61977654; called by muse, mutect2, varscan2
- RAPSN | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 88/326 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs528442857, COSV54085700; called by muse, mutect2, varscan2
- SLC4A2 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 84/639 reads (13%) | catalogued as rs916701727; called by muse, mutect2, varscan2
- SLC6A1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 167/491 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55115401; called by muse, mutect2, varscan2
- SLC6A2 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 97/370 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1297555256; called by muse, mutect2, varscan2
- STYXL2 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 88/283 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455748524; called by muse, mutect2, varscan2
- THSD7B | c.2801G>T p.W934L | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55721247; called by muse, mutect2, varscan2
- TSHZ2 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 66/441 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV61587369; called by muse, mutect2, varscan2
- ZNF727 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 240/557 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV70701560; called by muse, mutect2, varscan2
- ZNF99 | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 125/255 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs758972266, COSV68055922, COSV68056713; called by muse, mutect2, varscan2
- ACAP1 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ADAM21 | c.2002G>T p.G668W | Missense Mutation (SNP) | VAF 85/505 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH3B1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 95/385 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPK2 | c.2897C>T p.P966L | Missense Mutation (SNP) | VAF 123/398 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP45 | c.2510T>C p.L837P | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2orf49 | c.607A>C p.K203Q | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC168 | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 100/335 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- COL2A1 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 274/453 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CTC1 | c.2038_2044del p.F680Rfs*17 | Frame Shift Del (DEL) | VAF 38/286 reads (13%) | called by mutect2, pindel, varscan2
- DNM1 | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 124/382 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- JPH4 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 118/660 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, varscan2
- LOXL2 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 149/371 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LTBP1 | c.3146C>A p.A1049E (on ENST00000404816 / NM_206943.4; = p.A723E on NM_000627.4) | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MEI4 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MUC16 | c.31823C>A p.P10608Q | Missense Mutation (SNP) | VAF 144/398 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NCOR1 | c.4399C>T p.P1467S | Missense Mutation (SNP) | VAF 175/399 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA12 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 175/346 reads (51%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDCD11 | c.4537G>A p.E1513K | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PMM1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 110/435 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PP2D1 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 157/466 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPIL4 | c.1088A>T p.Y363F | Missense Mutation (SNP) | VAF 93/277 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PRR14 | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 152/472 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELN | c.10183G>A p.E3395K | Missense Mutation (SNP) | VAF 124/406 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RSRP1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 93/346 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- SCAPER | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- SGSM1 | c.3107_3108del p.E1036Afs*3 (on ENST00000400359 / NM_001039948.4; = p.E975Afs*3 on NM_133454.3) | Frame Shift Del (DEL) | VAF 40/283 reads (14%) | called by pindel, varscan2
- SH3GL1 | c.715A>C p.K239Q | Missense Mutation (SNP) | VAF 56/456 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SLCO3A1 | c.1044C>A p.N348K | Missense Mutation (SNP) | VAF 65/435 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SULT2B1 | c.796G>A p.D266N (on ENST00000201586 / NM_177973.2; = p.D251N on NM_004605.2) | Missense Mutation (SNP) | VAF 154/458 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- THOC1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 118/396 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBGCP6 | c.1618G>C p.V540L | Missense Mutation (SNP) | VAF 95/364 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UBR2 | c.3782G>A p.R1261K | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- YLPM1 | c.4045G>A p.D1349N | Missense Mutation (SNP) | VAF 151/476 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZC3H12B | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 169/246 reads (69%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC013489.1 | c.1503C>T p.I501= | Silent (SNP) | VAF 158/509 reads (31%) | catalogued as rs1323904227; called by muse, mutect2, varscan2
- ANK1 | c.2853C>T p.C951= | Silent (SNP) | VAF 249/601 reads (41%) | called by muse, mutect2, varscan2
- ANK2 | c.6561C>T p.F2187= | Silent (SNP) | VAF 160/481 reads (33%) | catalogued as rs950082624; called by muse, mutect2, varscan2
- BTBD16 | c.1101C>T p.G367= | Silent (SNP) | VAF 128/264 reads (48%) | catalogued as rs561462280, COSV53260598; called by muse, mutect2, varscan2
- CACNG5 | c.327C>T p.F109= | Silent (SNP) | VAF 128/382 reads (34%) | catalogued as COSV50059376; called by muse, mutect2, varscan2
- CDC42BPG | c.4098C>T p.F1366= | Silent (SNP) | VAF 65/266 reads (24%) | catalogued as rs1565670069; called by muse, mutect2, varscan2
- CDH6 | c.1785G>A p.G595= | Silent (SNP) | VAF 208/422 reads (49%) | catalogued as rs1289081425, COSV54070500; called by muse, mutect2, varscan2
- CORO7 | c.1218C>T p.L406= | Silent (SNP) | VAF 99/608 reads (16%) | catalogued as COSV52032619; called by muse, mutect2, varscan2
- CSNK1A1L | c.771C>A p.A257= | Silent (SNP) | VAF 121/407 reads (30%) | called by muse, mutect2, varscan2
- DNAJC1 | c.1035C>T p.F345= | Silent (SNP) | VAF 126/411 reads (31%) | called by muse, mutect2, varscan2
- ERBB4 | c.519C>A p.S173= | Silent (SNP) | VAF 75/303 reads (25%) | catalogued as rs1488063341; called by muse, mutect2, varscan2
- FAM135B | c.4116C>T p.N1372= | Silent (SNP) | VAF 84/517 reads (16%) | catalogued as COSV99425922; called by muse, mutect2, varscan2
- GABRA1 | c.384C>T p.F128= | Silent (SNP) | VAF 139/538 reads (26%) | catalogued as rs1219475284, COSV50121535; ClinVar: likely benign; called by muse, mutect2, varscan2
- HDAC5 | c.759C>T p.P253= | Silent (SNP) | VAF 130/300 reads (43%) | catalogued as rs1415912512; called by muse, mutect2, varscan2
- IQUB | c.1998C>T p.F666= | Silent (SNP) | VAF 44/288 reads (15%) | called by muse, mutect2, varscan2
- LCT | c.3639C>T p.I1213= | Silent (SNP) | VAF 93/354 reads (26%) | catalogued as rs940172090, COSV51545793; called by muse, mutect2, varscan2
- MAGEA12 | c.627C>T p.I209= | Silent (SNP) | VAF 96/355 reads (27%) | catalogued as rs1556833541, COSV100757111; called by muse, mutect2, varscan2
- MINK1 | c.2637C>T p.P879= | Silent (SNP) | VAF 126/298 reads (42%) | catalogued as COSV53418364, COSV99544723; called by muse, mutect2, varscan2
- MYH8 | c.1698C>T p.F566= | Silent (SNP) | VAF 58/413 reads (14%) | catalogued as rs772795789; called by muse, mutect2, varscan2
- NOD1 | c.883C>T p.L295= | Silent (SNP) | VAF 302/709 reads (43%) | catalogued as rs1006379265; called by muse, mutect2, varscan2
- PCDH10 | c.2553C>T p.N851= | Silent (SNP) | VAF 217/594 reads (37%) | called by muse, mutect2, varscan2
- PINK1 | c.324G>A p.L108= | Silent (SNP) | VAF 185/394 reads (47%) | called by muse, mutect2, varscan2
- PLIN4 | c.3804G>A p.T1268= (on ENST00000301286; = p.T1283= on NM_001367868.2) | Silent (SNP) | VAF 188/616 reads (31%) | catalogued as rs747687506, COSV100012450; called by muse, mutect2, varscan2
- POTED | c.1740G>A p.T580= | Silent (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2946G>A p.R982= | Silent (SNP) | VAF 70/550 reads (13%) | called by muse, mutect2, varscan2
- RYR2 | c.8742G>A p.T2914= | Silent (SNP) | VAF 95/289 reads (33%) | catalogued as rs751520306, COSV63670560; called by muse, mutect2, varscan2
- SLFN12L | c.279C>T p.F93= (on ENST00000260908 / NM_001363830.1; = p.F111= on NM_001195790.1) | Silent (SNP) | VAF 133/300 reads (44%) | catalogued as COSV53474187; called by muse, mutect2, varscan2
- TSC22D1 | c.96C>T p.G32= | Silent (SNP) | VAF 159/501 reads (32%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.1890C>T p.S630= | Silent (SNP) | VAF 213/598 reads (36%) | called by muse, mutect2, varscan2
- UBC | c.1951T>C p.L651= | Silent (SNP) | VAF 243/454 reads (54%) | catalogued as rs14564; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+7771G>A | Intron (SNP) | VAF 66/254 reads (26%) | catalogued as rs1213748649; called by muse, mutect2, varscan2
- PSMD8 | c.915+101T>C | Intron (SNP) | VAF 134/375 reads (36%) | called by muse, mutect2, varscan2
- VPS11 | c.-947A>G | 5'UTR (SNP) | VAF 58/247 reads (23%) | catalogued as rs782029499, COSV56185650; called by muse, mutect2, varscan2
